Gene-level copy-number profile of tumor specimen TCGA-85-8354-01A from TCGA case TCGA-85-8354, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 53.9 years (19,692 days).
Specimen TCGA-85-8354-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.4bc0d001-7368-4d61-88ae-dbb053edc255.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8354-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8b98dbe1-7a95-4d6e-a462-519a9160b369

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 1,357; copy number 2: 14,128; copy number 3: 19,890; copy number 4: 15,173; copy number 5: 5,344; copy number 6: 346; copy number 7: 559; copy number 8: 957; copy number 9: 1,150; copy number 10: 116; copy number 11: 387; copy number 12: 12; copy number 13: 189; copy number 15: 54; copy number 16: 21; copy number 18: 22; copy number 19: 25; copy number 20: 9; copy number 22: 4; copy number 39: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8354-01A-31D-2322-01): tumor purity 0.75, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–4): AL359922.1.
- chr9:21,892,188–27,104,728, 48 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,512 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:84,298,366–100,178,273, 282 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr1:107,056,674–107,505,448, 3 genes, copy number 18–22: PRMT6, NTNG1, NDUFA4P1.
- chr1:168,576,605–170,304,358, 42 genes, copy number 7 (within-gene range 4–7): XCL1, AL031736.2, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, AL135926.2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1, NME7, Z99758.1, BLZF1, CCDC181, SLC19A2, AL021068.1, Z99572.1, F5, SELP, C1orf112, SELL, SELE, AL021940.1, METTL18, SCYL3, RN7SL333P, AL031297.1, KIFAP3, RN7SL269P, MRPS10P1, AL356475.1, SIGLEC30P, METTL11B, MIR3119-2, MIR3119-1, LINC01681, ISCUP1, LINC01142.
- chr2:12,411,398–12,411,501, 1 gene, copy number 10: RNU6-843P.
- chr2:54,253,178–70,125,317, 282 genes, copy number 7–13 (broad region; genes not listed).
- chr2:81,983,272–85,310,387, 38 genes, copy number 7 (within-gene range 4–7): AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1, FUNDC2P2, AC106874.1, SUCLG1, DNAH6, DUXAP1, LDHAP7, TRABD2A, AC010087.1, RPL12P18, TMSB10, RPS2P17, AC022210.1, KCMF1, LINC01964, AC078974.1, LSM3P3, TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11.
- chr3:88,051,944–91,513,775, 21 genes, copy number 8–12: CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr3:148,368,384–198,222,513, 897 genes, copy number 8–11 (broad region; genes not listed).
- chr4:51,843,000–60,922,684, 145 genes, copy number 8–22 (broad region; genes not listed).
- chr4:62,248,294–62,292,337, 2 genes, copy number 9: RPL21P47, AC105313.1.
- chr5:50,665,899–51,101,643, 9 genes, copy number 8 (within-gene range 5–8): PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1.
- chr6:41,789,896–41,895,361, 1 gene, copy number 8 (within-gene range 2–8): USP49.
- chr6:41,832,854–44,184,401, 93 genes, copy number 8 (broad region; genes not listed).
- chr7:7,906,519–8,262,687, 8 genes, copy number 9 (within-gene range 5–9): RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT, GLCCI1, AC006042.2, ICA1, AC006042.1.
- chr7:24,537,332–65,463,438, 821 genes, copy number 7–18 (broad region; genes not listed).
- chr8:33,226,848–34,039,104, 21 genes, copy number 16 (within-gene range 3–16): AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4.
- chr9:27,109,141–28,670,286, 16 genes, copy number 20–39 (within-gene range 0–39): TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1.
- chr11:67,965,873–70,436,584, 74 genes, copy number 11–15 (broad region; genes not listed).
- chr11:70,477,277–70,477,592, 1 gene, copy number 15: AP001271.1.
- chr12:18,493,051–33,718,217, 277 genes, copy number 8–11 (broad region; genes not listed).
- chr12:66,347,431–67,069,162, 1 gene, copy number 7 (within-gene range 5–7): GRIP1.
- chr12:66,950,754–67,753,817, 15 genes, copy number 7: AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1.
- chr18:29,256,817–32,774,413, 61 genes, copy number 7–11 (broad region; genes not listed).
- chr19:11,483,427–17,864,153, 375 genes, copy number 8–9 (within-gene range 3–9) (broad region; genes not listed).
- chr21:23,352,929–25,381,756, 26 genes, copy number 7 (within-gene range 4–7): D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684, LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1.

Autosomal genes at a single copy (total copy number 1): 501. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
